Gene-level copy-number profile of tumor specimen REBC-AF7J-TTM1-A from REBC case REBC-AF7J, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: male; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-AF7J-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 40bb9407-525c-4d0e-b0e4-5fd37141e183.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-AF7J-NB1-SC208320 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/e0a8fa6c-bc4b-4481-979e-f043aa0fe40d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 4,672; copy number 2: 54,002; copy number 3: 210; copy number 4: 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:132,147,591–132,257,969, 4 genes (within-gene range 0–2): ANKRD30BL, RNU6-1132P, RNA5-8SP5, MIR663B.
- chr6:126,590,287–126,590,393, 1 gene: RNU6-200P.
- chr9:62,686,912–62,845,184, 9 genes: ATP5F1AP7, SDR42E1P3, FKBP4P7, LINC01410, AL512625.3, RNA5SP283, AL512625.2, PTGER4P2, CDK2AP2P2.
- chr9:62,857,208–62,864,957, 2 genes (within-gene range 0–1): MYO5BP2, ADGRF5P1.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,816. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
